Somatic mutation profile of tumor specimen TCGA-CG-5730-01A (aliquot TCGA-CG-5730-01A-11D-1600-08) from TCGA case TCGA-CG-5730, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 80.6 years (29,432 days).
Specimen TCGA-CG-5730-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d3ca168-ecf3-47e1-8a15-1f3e995c85dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CG-5730-11A (Solid Tissue Normal), aliquot TCGA-CG-5730-11A-01D-1600-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49f1503f-5da1-48d6-ba5a-680689cebf9c

The open-access MAF lists 171 somatic variants for this specimen: 114 protein-altering or splice-affecting, 50 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 102, Silent 50, Nonsense Mutation 5, Frame Shift Ins 4, RNA 3, Intron 2, Frame Shift Del 2, In Frame Del 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 28/34 reads (82%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC006059.2 | c.463G>A p.V155M | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.04); catalogued as rs530423995, COSV59606311; called by muse, mutect2, varscan2
- ADAM20 | c.326G>A p.C109Y | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56454509; called by muse, mutect2, varscan2
- AFF2 | c.2140G>C p.D714H | Missense Mutation (SNP) | VAF 132/324 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM128721, COSV53983360; called by muse, mutect2, varscan2
- ASXL3 | c.4894G>A p.E1632K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.09); catalogued as COSV52462181, COSV99325833; called by muse, mutect2, varscan2
- ATP1A2 | c.2212G>A p.V738I | Missense Mutation (SNP) | VAF 83/117 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as rs1558008569, COSV63403100; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP2B2 | c.2071G>A p.V691M (on ENST00000352432; = p.V657M on NM_001683.5) | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1211251049, COSV100660273, COSV59492940; called by muse, mutect2, varscan2
- AVP | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 121/278 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs747008249, COSV66671760; called by muse, mutect2, varscan2
- BASP1 | c.43A>T p.N15Y | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59470150; called by muse, mutect2, varscan2
- BCL9L | c.1478C>T p.P493L | Missense Mutation (SNP) | VAF 44/188 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs781404269, COSV52683193; called by muse, mutect2, varscan2
- BRAP | c.254A>T p.K85I | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV58155282; called by muse, mutect2, varscan2
- BUB1 | c.2587G>C p.V863L | Missense Mutation (SNP) | VAF 67/261 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.137); catalogued as COSV57062290; called by muse, mutect2, varscan2
- CADPS | c.3154G>A p.A1052T | Missense Mutation (SNP) | VAF 56/170 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV51869190; called by muse, mutect2, varscan2
- CASP14 | c.583T>A p.F195I | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.997); catalogued as COSV55665121, COSV55665995; called by muse, mutect2, varscan2
- CCDC39 | c.1709G>A p.R570H | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs369208682; called by muse, mutect2
- CEP350 | c.6790A>G p.T2264A | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62600415; called by muse, mutect2, varscan2
- CHGB | c.2004G>T p.K668N | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV66759994, COSV66760037; called by muse, mutect2, varscan2
- CNGB3 | c.1064G>A p.R355Q | Missense Mutation (SNP) | VAF 47/209 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs555345043, COSV60684228; called by muse, mutect2, varscan2
- CSMD2 | c.1669A>G p.K557E | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as COSV53897668; called by muse, mutect2, varscan2
- CSMD3 | c.1027C>G p.Q343E | Missense Mutation (SNP) | VAF 159/300 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs868150877, COSV52142728, COSV52181099; called by muse, mutect2, varscan2
- DCLRE1A | c.2081G>A p.G694E | Missense Mutation (SNP) | VAF 134/655 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as rs1254334824, COSV63748399; called by muse, mutect2, varscan2
- DEK | c.503G>C p.R168T | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as COSV55237055; called by muse, varscan2
- DOCK4 | c.4625G>A p.R1542Q | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.82); PolyPhen benign (0.041); catalogued as rs761423302, COSV70235114, COSV70243241; called by muse, mutect2, varscan2
- EIF2D | c.688C>T p.H230Y | Missense Mutation (SNP) | VAF 64/293 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV55113040; called by muse, mutect2, varscan2
- EIPR1 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.083); catalogued as rs141014675, COSV66128928; called by muse, mutect2, varscan2
- EPS8L2 | c.1499T>G p.L500R | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.8); PolyPhen benign (0.015); catalogued as COSV59347387; called by muse, mutect2, varscan2
- ERCC6 | c.1367G>A p.G456E | Missense Mutation (SNP) | VAF 64/162 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1435459745, COSV63388884; called by muse, mutect2, varscan2
- EVPL | c.6097C>T p.R2033C | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs367732326; called by muse, mutect2, varscan2
- FAM110A | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55726650; called by muse, mutect2, varscan2
- FAT4 | c.13307C>T p.P4436L | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as rs760631255, COSV58677974, COSV58693071; called by muse, mutect2, varscan2
- FBLN1 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as rs573352225, COSV53045343; called by muse, mutect2, varscan2
- FGD6 | c.2271A>G p.I757M | Missense Mutation (SNP) | VAF 63/227 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV59691786; called by muse, mutect2, varscan2
- FLG | c.9829C>T p.R3277C | Missense Mutation (SNP) | VAF 111/961 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs918420067, COSV64239504; called by muse, mutect2, varscan2
- FRYL | c.2530A>T p.S844C | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs747521211, COSV51943852; called by muse, mutect2, varscan2
- FSHR | c.791T>A p.L264H | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58620826, COSV58636901; called by muse, mutect2, varscan2
- GEMIN7 | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54319451; called by muse, mutect2, varscan2
- GGCT | c.11C>A p.S4* | Nonsense Mutation (SNP) | VAF 45/182 reads (25%) | catalogued as COSV50040773; called by muse, mutect2, varscan2
- GHR | c.83T>A p.I28N | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as COSV50109162; called by muse, mutect2, varscan2
- GLI3 | c.4420G>A p.A1474T | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs370009188; called by muse, mutect2, varscan2
- GPC6 | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0.119); catalogued as COSV65505480; called by muse, mutect2
- GPR151 | c.972_974del p.M324del | In Frame Del (DEL) | VAF 30/68 reads (44%) | catalogued as rs996034894; called by pindel, varscan2
- GPR155 | c.76C>A p.H26N | Missense Mutation (SNP) | VAF 51/280 reads (18%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV55038206; called by muse, mutect2, varscan2
- HCCS | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 48/296 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV58238964; called by muse, mutect2, varscan2
- HDAC5 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as rs746035403, COSV56817977; called by muse, mutect2, varscan2
- HIVEP3 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 91/353 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs199627359, COSV56012791; called by muse, mutect2, varscan2
- HJURP | c.1327C>T p.R443W | Missense Mutation (SNP) | VAF 41/183 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs750138498, COSV64978654; called by muse, mutect2, varscan2
- HMCN1 | c.8980C>G p.P2994A | Missense Mutation (SNP) | VAF 37/182 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV54889036; called by muse, mutect2, varscan2
- HTATIP2 | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 23/76 reads (30%) | catalogued as COSV70041119; called by muse, mutect2, varscan2
- INPP5B | c.1502G>A p.R501Q (on ENST00000373023; = p.R421Q on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/159 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs202221695, COSV65960127; called by muse, mutect2, varscan2
- ITGAV | c.504G>T p.E168D | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53710835; called by muse, mutect2, varscan2
- KCNB2 | c.1876G>A p.A626T | Missense Mutation (SNP) | VAF 95/213 reads (45%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.066); catalogued as rs139648032; called by muse, mutect2, varscan2
- KIF18A | c.1420G>C p.E474Q | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.559); catalogued as COSV54182109; called by muse, mutect2, varscan2
- KRTAP10-9 | c.60C>G p.D20E | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.867); catalogued as COSV59956915; called by muse, mutect2, varscan2
- LAT2 | c.457C>T p.Q153* | Nonsense Mutation (SNP) | VAF 11/39 reads (28%) | catalogued as COSV51920925; called by muse, mutect2, varscan2
- LCT | c.1219G>C p.G407R | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51546571, COSV51558873; called by muse, mutect2, varscan2
- MAGEA1 | c.697G>T p.G233W | Missense Mutation (SNP) | VAF 74/308 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.455); catalogued as COSV63118358; called by muse, mutect2, varscan2
- MAGEC1 | c.1860A>T p.E620D | Missense Mutation (SNP) | VAF 193/875 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV53570435; called by muse, mutect2, varscan2
- MAMLD1 | c.1951G>A p.A651T | Missense Mutation (SNP) | VAF 61/263 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.199); catalogued as rs1557406696, COSV53373436; called by muse, mutect2, varscan2
- MAZ | c.122C>G p.P41R | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.432); catalogued as COSV50714411, COSV50717004; called by muse, mutect2, varscan2
- MLLT3 | c.1081C>A p.P361T | Missense Mutation (SNP) | VAF 75/108 reads (69%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.831); catalogued as COSV63496531; called by muse, mutect2, varscan2
- MTMR14 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368196455; called by muse, mutect2, varscan2
- MYCBP2 | c.3193C>T p.L1065F (on ENST00000357337; = p.L1103F on NM_015057.5) | Missense Mutation (SNP) | VAF 36/243 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV62014168; called by muse, mutect2, varscan2
- MYEF2 | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 67/277 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV51046816; called by muse, mutect2, varscan2
- NCAPH | c.1745C>T p.P582L | Missense Mutation (SNP) | VAF 96/435 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.257); catalogued as rs866038280, COSV53635772; called by muse, mutect2, varscan2
- OBSL1 | c.4223C>T p.A1408V | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV54704679; called by muse, mutect2, varscan2
- OR1N2 | c.505G>A p.V169M | Missense Mutation (SNP) | VAF 90/179 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as rs754685404, COSV65460465; called by muse, mutect2, varscan2
- PCDH17 | c.1036G>A p.D346N | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64973085; called by muse, mutect2, varscan2
- PCDHA2 | c.1142C>T p.T381M | Missense Mutation (SNP) | VAF 137/168 reads (82%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.663); catalogued as rs781833045, COSV65366021; called by muse, mutect2, varscan2
- PCSK1 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773564429, COSV60734530; called by muse, mutect2, varscan2
- PEX5L | c.1595C>T p.T532M | Missense Mutation (SNP) | VAF 89/307 reads (29%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); catalogued as COSV55842658; called by muse, mutect2, varscan2
- PHF19 | c.1097C>T p.S366F | Missense Mutation (SNP) | VAF 17/264 reads (6%) | SIFT tolerated (0.67); PolyPhen benign (0.027); catalogued as COSV65877891; called by muse, mutect2
- PHF8 | c.599G>A p.R200H (on ENST00000357988 / NM_001184896.1; = p.R164H on NM_015107.3) | Missense Mutation (SNP) | VAF 101/210 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as rs1333636508, COSV57679439; called by muse, mutect2, varscan2
- PI3 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 45/171 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.188); catalogued as rs780306943, COSV54783016, COSV54783391; called by muse, mutect2, varscan2
- PLB1 | c.1205C>T p.T402M | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780761178, COSV59819843, COSV59822334; called by muse, mutect2, varscan2
- POLR2A | c.4808G>A p.R1603H | Missense Mutation (SNP) | VAF 66/183 reads (36%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.737); catalogued as rs1036541727; called by muse, mutect2, varscan2
- PPDPFL | c.43C>A p.Q15K | Missense Mutation (SNP) | VAF 40/211 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV57460634, COSV57460932; called by muse, mutect2, varscan2
- PSG5 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 87/366 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs764836747, COSV61653369; called by muse, mutect2
- RAB3GAP1 | c.226C>T p.H76Y | Missense Mutation (SNP) | VAF 61/218 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV51480594; called by muse, mutect2, varscan2
- RYR2 | c.10676T>C p.F3559S | Missense Mutation (SNP) | VAF 59/170 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV63675746; called by muse, mutect2, varscan2
- SEMA5A | c.367G>T p.V123L | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.075); catalogued as COSV66788950; called by muse, mutect2, varscan2
- SF3B4 | c.1219A>T p.T407S | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV54964812; called by muse, mutect2, varscan2
- SLFN12 | c.553T>A p.F185I | Missense Mutation (SNP) | VAF 52/814 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV59225592; called by muse, mutect2
- SLIT2 | c.1289A>C p.N430T | Missense Mutation (SNP) | VAF 69/210 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56566796, COSV99062667; called by muse, mutect2, varscan2
- SMOC2 | c.914C>T p.P305L (on ENST00000356284 / NM_001166412.2; = p.P316L on NM_022138.3) | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs148223188, COSV62436013; called by muse, mutect2, varscan2
- SPATA31E1 | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.68); PolyPhen benign (0.187); catalogued as COSV57790539; called by muse, mutect2, varscan2
- SRRM4 | c.1463G>A p.R488Q | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV57412531; called by muse, mutect2, varscan2
- STARD3 | c.581G>T p.G194V | Missense Mutation (SNP) | VAF 417/583 reads (72%) | SIFT deleterious (0.02); PolyPhen benign (0.217); catalogued as COSV60419558; called by muse, mutect2, varscan2
- STPG2 | c.1274G>A p.R425H | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as rs779688604, COSV54792040; called by muse, mutect2, varscan2
- TAF15 | c.1555C>T p.R519* (on ENST00000605844 / NM_139215.3; = p.R516* on NM_003487.4) | Nonsense Mutation (SNP) | VAF 15/178 reads (8%) | catalogued as rs939246294; called by muse, mutect2
- TCERG1L | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV64048565; called by muse, mutect2, varscan2
- THOC1 | c.107C>T p.T36I | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV55274558; called by muse, mutect2, varscan2
- TNXB | c.8108G>A p.R2703H (on ENST00000647633; = p.R2456H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.061); catalogued as rs866389765, COSV64476337; called by muse, mutect2, varscan2
- TRRAP | c.9511C>T p.R3171W (on ENST00000359863 / NM_001244580.1; = p.R3142W on NM_003496.3) | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs778465879, COSV62838500; called by muse, mutect2, varscan2
- TTC13 | c.1930C>T p.R644W | Missense Mutation (SNP) | VAF 55/281 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs777402164, COSV64168080; called by muse, mutect2, varscan2
- TTN | c.55071G>A p.W18357* (on ENST00000591111; = p.W10933* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 31/123 reads (25%) | catalogued as COSV100620717, COSV59966972; called by muse, mutect2, varscan2
- TTN | c.39781G>A p.A13261T (on ENST00000591111; = p.A5837T on NM_003319.4) | Missense Mutation (SNP) | VAF 73/150 reads (49%) | PolyPhen benign (0.001); catalogued as COSV59967000; called by muse, mutect2, varscan2
- TULP1 | c.1537G>A p.A513T | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.214); catalogued as COSV57692267; called by muse, mutect2, varscan2
- USP48 | c.2216C>T p.T739M | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs550144846, COSV57608610; called by muse, mutect2, varscan2
- VWF | c.6274G>A p.G2092R | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.387); catalogued as rs767280593, COSV54615867; called by muse, mutect2, varscan2
- WWP1 | c.2468G>A p.R823K | Missense Mutation (SNP) | VAF 15/240 reads (6%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.944); catalogued as COSV55357805, COSV55363293; called by muse, mutect2
- ZDHHC18 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs749761834, COSV65145226; called by muse, mutect2, varscan2
- ZNF211 | c.512C>T p.S171L (on ENST00000347302 / NM_198855.4; = p.S184L on NM_006385.5) | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs767942979, COSV53739673; called by muse, mutect2
- ZNF578 | c.1676G>A p.R559K | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.892); catalogued as COSV69735913, COSV69736258; called by muse, mutect2
- ZNF99 | c.1982C>A p.S661Y | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT tolerated (1); PolyPhen possibly damaging (0.552); catalogued as COSV101233904, COSV68055333; called by muse, mutect2, varscan2
- CNKSR2 | c.1779dup p.Y594Ifs*15 | Frame Shift Ins (INS) | VAF 50/343 reads (15%) | called by mutect2, pindel, varscan2
- CNTN3 | c.2537dup p.G847Wfs*8 | Frame Shift Ins (INS) | VAF 33/144 reads (23%) | called by mutect2, pindel, varscan2
- CRISPLD1 | c.679T>A p.C227S | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- GAS2L2 | c.1088G>A p.C363Y | Missense Mutation (SNP) | VAF 27/374 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.086); called by muse, mutect2
- LAMB1 | c.2913del p.S972Rfs*89 | Frame Shift Del (DEL) | VAF 38/155 reads (25%) | called by mutect2, pindel, varscan2
- MMP28 | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 5/104 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- MRC1 | c.1886C>A p.A629E | Missense Mutation (SNP) | VAF 131/365 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR51B6 | c.573del p.F192Sfs*8 | Frame Shift Del (DEL) | VAF 38/116 reads (33%) | called by mutect2, pindel, varscan2
- RGS21 | c.441dup p.W148Mfs*13 | Frame Shift Ins (INS) | VAF 15/109 reads (14%) | called by mutect2, pindel, varscan2
- ZKSCAN7 | c.910dup p.V304Gfs*13 | Frame Shift Ins (INS) | VAF 53/179 reads (30%) | called by mutect2, pindel, varscan2
- ABCA5 | c.2313C>A p.V771= | Silent (SNP) | VAF 20/379 reads (5%) | catalogued as COSV67016260; called by muse, mutect2
- ADAM15 | c.636C>G p.T212= | Silent (SNP) | VAF 23/105 reads (22%) | catalogued as COSV55057629; called by muse, mutect2, varscan2
- ADGRB3 | c.2403G>A p.S801= | Silent (SNP) | VAF 56/183 reads (31%) | catalogued as rs773510249, COSV65390306; called by muse, mutect2, varscan2
- CABP5 | c.216C>T p.L72= | Silent (SNP) | VAF 72/135 reads (53%) | catalogued as rs757439989, COSV53152390; called by muse, mutect2, varscan2
- CTSW | c.363T>A p.S121= | Silent (SNP) | VAF 26/89 reads (29%) | catalogued as COSV57172067; called by muse, mutect2, varscan2
- CXCR5 | c.477C>T p.R159= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV52683184, COSV52683451; called by muse, mutect2, varscan2
- DKKL1 | c.111C>T p.D37= | Silent (SNP) | VAF 21/139 reads (15%) | catalogued as rs763792602, COSV55561957; called by muse, mutect2, varscan2
- FGF3 | c.672C>T p.H224= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs375708730, COSV61925621; called by muse, mutect2
- FYB2 | c.528G>T p.G176= | Silent (SNP) | VAF 49/162 reads (30%) | catalogued as COSV58583817; called by muse, mutect2, varscan2
- GATA1 | c.1161G>T p.L387= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as COSV64961886; called by muse, mutect2, varscan2
- GATA5 | c.864G>A p.Q288= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV53345567; called by muse, mutect2
- GLUD1 | c.1347C>T p.V449= | Silent (SNP) | VAF 10/300 reads (3%) | catalogued as COSV99517953; called by muse, mutect2
- GLYAT | c.594G>A p.E198= | Silent (SNP) | VAF 41/189 reads (22%) | catalogued as rs749236606, COSV53538878; called by muse, mutect2, varscan2
- GPR3 | c.876C>T p.I292= | Silent (SNP) | VAF 26/199 reads (13%) | catalogued as COSV64994582; called by muse, mutect2, varscan2
- KBTBD7 | c.234G>A p.T78= | Silent (SNP) | VAF 8/108 reads (7%) | catalogued as COSV101068014, COSV65266208; called by muse, mutect2
- KNTC1 | c.5037C>T p.L1679= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV61079456; called by muse, mutect2, varscan2
- LNPEP | c.978C>T p.T326= | Silent (SNP) | VAF 87/281 reads (31%) | catalogued as rs770751835, COSV51477080; called by muse, mutect2, varscan2
- LRP1B | c.6315C>T p.N2105= | Silent (SNP) | VAF 84/172 reads (49%) | catalogued as rs1028832478, COSV67201876; called by muse, mutect2, varscan2
- LSMEM1 | c.360C>T p.L120= | Silent (SNP) | VAF 58/230 reads (25%) | catalogued as rs767104959, COSV57196206; called by muse, varscan2
- MAGEB6 | c.498T>C p.Y166= | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as rs1161514254, COSV66872074; called by muse, mutect2, varscan2
- MAGEB6B | c.1092T>C p.Y364= | Silent (SNP) | VAF 111/246 reads (45%) | called by muse, mutect2, varscan2
- NKAPL | c.213G>A p.S71= | Silent (SNP) | VAF 65/105 reads (62%) | catalogued as rs764734759, COSV59197385; called by muse, mutect2, varscan2
- OR10G8 | c.384G>A p.P128= | Silent (SNP) | VAF 55/217 reads (25%) | catalogued as rs1331551730, COSV70908394; called by muse, mutect2, varscan2
- PIK3C3 | c.852C>T p.H284= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as rs762755261, COSV56277663; called by muse, mutect2, varscan2
- PLK4 | c.633C>T p.F211= | Silent (SNP) | VAF 71/193 reads (37%) | catalogued as rs761455609, COSV54636930; called by muse, mutect2, varscan2
- PORCN | c.735C>T p.Y245= (on ENST00000326194 / NM_203475.3; = p.Y234= on NM_022825.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 64/188 reads (34%) | catalogued as COSV58225822; called by muse, mutect2, varscan2
- RTN2 | c.600C>T p.P200= | Silent (SNP) | VAF 8/109 reads (7%) | catalogued as rs886386424, COSV55593332; called by muse, mutect2
- SIAH2 | c.336G>A p.P112= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV57261974; called by muse, mutect2, varscan2
- SLAMF1 | c.192C>T p.V64= | Silent (SNP) | VAF 31/189 reads (16%) | catalogued as COSV52498505, COSV99349324; called by muse, mutect2, varscan2
- SLC12A9 | c.513C>T p.G171= | Silent (SNP) | VAF 25/88 reads (28%) | catalogued as COSV51932301; called by muse, mutect2, varscan2
- SLC22A1 | c.99G>A p.A33= | Silent (SNP) | VAF 46/208 reads (22%) | catalogued as rs560595462, COSV61451970; called by muse, mutect2, varscan2
- SLC2A1 | c.1095C>A p.S365= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV65287127; called by muse, mutect2
- SLC30A6 | c.142C>T p.L48= | Silent (SNP) | VAF 60/307 reads (20%) | catalogued as COSV50872183; called by muse, mutect2, varscan2
- SLITRK4 | c.471G>A p.L157= | Silent (SNP) | VAF 62/357 reads (17%) | catalogued as COSV62022900; called by muse, mutect2, varscan2
- SPAG17 | c.3939G>A p.R1313= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as COSV60455988; called by muse, mutect2
- SULT1C4 | c.612G>A p.K204= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as COSV55597585; called by muse, mutect2, varscan2
- SYNDIG1 | c.291C>T p.G97= | Silent (SNP) | VAF 34/161 reads (21%) | catalogued as rs146291718; called by muse, mutect2, varscan2
- TBC1D8 | c.1239C>G p.L413= | Silent (SNP) | VAF 29/96 reads (30%) | catalogued as rs745592536, COSV65211224, COSV65216011; called by muse, mutect2, varscan2
- TBKBP1 | c.762C>T p.C254= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs1249853285, COSV64653455; called by muse, mutect2
- TECPR1 | c.2184G>A p.P728= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as rs775757627, COSV65782979, COSV65784091; called by muse, mutect2, varscan2
- TEP1 | c.228C>T p.S76= | Silent (SNP) | VAF 50/197 reads (25%) | catalogued as COSV52990507; called by muse, mutect2, varscan2
- TMLHE | c.531G>A p.L177= | Silent (SNP) | VAF 28/405 reads (7%) | catalogued as COSV57686858; called by muse, mutect2
- TOGARAM1 | c.120C>T p.G40= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV61887756; called by muse, mutect2, varscan2
- TRAF7 | c.1821C>T p.V607= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV58213561; called by muse, mutect2, varscan2
- TRAPPC9 | c.2580C>T p.F860= | Silent (SNP) | VAF 41/203 reads (20%) | catalogued as COSV66896403; called by muse, mutect2, varscan2
- TRIM9 | c.327G>A p.P109= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs755021967, COSV53614952; called by muse, mutect2, varscan2
- TRPC5 | c.1851G>A p.L617= | Silent (SNP) | VAF 143/752 reads (19%) | catalogued as COSV53287175; called by muse, mutect2, varscan2
- UBE3A | c.1653G>A p.L551= | Silent (SNP) | VAF 6/90 reads (7%) | catalogued as rs1275928808, COSV51663255; called by muse, mutect2
- UPK3B | c.189G>A p.E63= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV56859837; called by muse, mutect2, varscan2
- ZNF583 | c.207G>A p.K69= | Silent (SNP) | VAF 64/158 reads (41%) | catalogued as COSV52401673; called by muse, mutect2, varscan2
- CA6 | c.259+2121G>A | Intron (SNP) | VAF 12/22 reads (55%) | catalogued as rs1368230889, COSV101077398; called by muse, mutect2, varscan2
- GALNT17 | c.-1G>A | 5'UTR (SNP) | VAF 6/11 reads (55%) | catalogued as rs1474954834; called by muse, mutect2, varscan2
- MICAL3 | c.2241+4653C>G | Intron (SNP) | VAF 17/158 reads (11%) | catalogued as COSV99260188; called by muse, varscan2
- MIR382 | n.43G>T | RNA (SNP) | VAF 22/76 reads (29%) | called by muse, mutect2, varscan2
- MIR545 | n.38A>C | RNA (SNP) | VAF 27/107 reads (25%) | called by muse, mutect2, varscan2
- SMIM29 | c.*154C>T | 3'UTR (SNP) | VAF 9/41 reads (22%) | catalogued as COSV58988332; called by muse, mutect2, varscan2
- STAG3L4 | n.525G>T | RNA (SNP) | VAF 42/141 reads (30%) | called by muse, mutect2, varscan2
